Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAFH, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAFH-01A (Primary Tumor).

ICD O-3
Seminoma NOS 9061/3
Site Testis NOS C62.9
JW 3/3/14

Concerning

Summary pathology report

Left orchidectomy; seminoma; diameter 2 cm; tumor confined to testis in available slides; no angio-invasion; no rete testis present in the available slides.

Date of procurement (= date of orchidectomy)

pathologist

professor of pathology

Source: NCI Genomic Data Commons file a4fa14b8-34c2-419b-a80b-c3c230aab0fb (TCGA-2G-AAFH.6F5C875D-1C2C-48BA-9B6B-58AA33236C09.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).